CCDI case PBCDPH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/c9d7889f-681f-443f-ac1c-6268acb40a1f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 8.9 years (3,256 days).

Biospecimens (3 samples)
- Sample 0DPX35: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPX3F: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPX3Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
